CCDI case PBCLME — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/ed7582d6-8e78-4c5e-8185-3268e82b9ff5

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 16.7 years (6,091 days).

Biospecimens (3 samples)
- Sample 0DUKGX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKIJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUKIZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
